TARGET case TARGET-30-PAMRZD — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Adrenal gland. Index date: not stated by GDC for this case (day counts are relative to an unstated reference).
https://portal.gdc.cancer.gov/cases/1e5dee0f-fe98-594a-aa5a-ec4a0300a87a

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 2.8 years (1,009 days); Year of diagnosis: 2003; Days to last follow up: 5,488 days (15.0 years); INSS stage: Stage 4.
